Gene-level copy-number profile of tumor specimen ALCH-B1U7-TTP1-A from ALCHEMIST case ALCH-B1U7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,044 days).
Specimen ALCH-B1U7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e20a404e-091b-49dd-9bf4-fffb1fd717d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1U7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/e750d0c0-0ad9-4c22-b13e-ee12436a68d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 4,650; copy number 2: 51,927; copy number 3: 1,747; copy number 5: 5; copy number 6: 3; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:132,060,655–132,076,170, 2 genes: IL3, CSF2.
- chr6:73,322,837–73,417,566, 9 genes (within-gene range 0–2): SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr7:129,756,266–129,785,185, 5 genes (within-gene range 0–2): RNA5SP244, MIR182, MIR96, MIR183, AC084864.1.
- chr7:149,069,641–149,183,042, 4 genes: ZNF786, ZNF425, RN7SL521P, ZNF398.
- chr7:152,463,786–152,465,549, 1 gene: LINC01003.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:63,543,569–63,544,664, 1 gene: AL136038.3.
- chr16:58,665,109–58,706,297, 2 genes: SLC38A7, AC012183.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,027,678–1,028,972, 1 gene, copy number 5: AC019103.1.
- chr4:1,113,639–1,153,726, 4 genes, copy number 5: AC092535.4, TMED11P, AC092535.1, AC092535.2.
- chr14:105,664,633–105,669,843, 1 gene, copy number 7 (within-gene range 2–7): IGHGP.
- chr19:5,782,960–5,791,225, 3 genes, copy number 6: PRR22, AC011499.1, DUS3L.
- chr21:44,158,740–44,160,076, 1 gene, copy number 7: LINC01678.

Autosomal genes at a single copy (total copy number 1): 2,776. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
